TCGA case TCGA-GS-6629 — Lymphoid Neoplasm Diffuse Large B-cell Lymphoma (TCGA-DLBC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Primary site: Hematopoietic and reticuloendothelial systems; Tissue source site: Fundacio Clinic per a la Recerca Biomedica.
https://portal.gdc.cancer.gov/cases/dac5f5db-1a2a-47f9-8d46-a3d4eed0864b

Biospecimens (2 samples)
- Samples TCGA-GS-6629-10A, TCGA-GS-6629-10B (2 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
